Somatic mutation profile of tumor specimen MP2PRT-PAUMRK-TMP1-A (aliquot MP2PRT-PAUMRK-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUMRK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,248 days).
Specimen MP2PRT-PAUMRK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e1d64ec-7dd1-4103-b64c-0273ea9e3df8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMRK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMRK-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03a20912-8d43-4922-8f7c-7a7425347529

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 14, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772805812, COSV99898978; called by muse, mutect2
- DCAF8 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs1327588458; called by muse, mutect2, varscan2
- GAMT | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752002577; called by muse, mutect2, varscan2
- LIG1 | c.2557C>G p.P853A | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99618963; called by muse, mutect2, varscan2
- MAPK1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV53184825; called by muse, mutect2, varscan2
- NOL7 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV63081231, COSV99061816; called by muse, mutect2, varscan2
- PCDHB12 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 283/778 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV53392735, COSV53399515; called by muse, mutect2, varscan2
- SMAD9 | c.851G>A p.R284Q (on ENST00000379826 / NM_001127217.3; = p.R247Q on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs371433324; called by muse, mutect2, varscan2
- SOBP | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 78/555 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.577); catalogued as COSV100433021; called by muse, mutect2, varscan2
- SRRM4 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as rs376151397, COSV57416220; called by muse, mutect2, varscan2
- TLN1 | c.4091A>G p.D1364G | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1257016674; called by muse, mutect2, varscan2
- TOE1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 65/567 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59152861; called by muse, mutect2, varscan2
- ABCC12 | c.2184G>C p.E728D | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- ANKRD11 | c.1926G>C p.E642D | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CCDC180 | c.4875G>C p.K1625N | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CNTRL | c.6471G>C p.M2157I | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- COL6A6 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 178/462 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EDEM1 | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRY | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, varscan2
- GALNTL6 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 101/289 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GAPDHS | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2
- HEPH | c.2504C>G p.S835C (on ENST00000343002; = p.S568C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS12 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IQGAP1 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KPNA3 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MARCHF2 | c.431G>C p.C144S | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PACS2 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PLXNB2 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- POPDC3 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 42/297 reads (14%) | called by muse, varscan2
- USH2A | c.12228G>C p.Q4076H | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CCM2L | c.108C>T p.R36= | Silent (SNP) | VAF 79/509 reads (16%) | called by muse, mutect2, varscan2
- DDX27 | c.312C>T p.V104= | Silent (SNP) | VAF 46/286 reads (16%) | called by muse, mutect2, varscan2
- DTX4 | c.315C>T p.Y105= | Silent (SNP) | VAF 176/437 reads (40%) | catalogued as rs376164008; called by muse, mutect2, varscan2
- FAT4 | c.12498C>T p.G4166= | Silent (SNP) | VAF 93/240 reads (39%) | catalogued as rs190749052; called by muse, mutect2, varscan2
- H2BC14 | c.285C>T p.I95= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as COSV100297553; called by muse, mutect2
- LYNX1-SLURP2 | c.381C>T p.L127= | Silent (SNP) | VAF 52/319 reads (16%) | called by muse, mutect2, varscan2
- NDUFAF3 | c.15C>T p.L5= | Silent (SNP) | VAF 66/405 reads (16%) | called by muse, mutect2, varscan2
- NID2 | c.2625C>T p.F875= | Silent (SNP) | VAF 85/474 reads (18%) | called by muse, mutect2, varscan2
- NLRP13 | c.3000C>G p.L1000= | Silent (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1614C>T p.L538= | Silent (SNP) | VAF 19/707 reads (3%) | called by muse, mutect2
- PRSS37 | c.99C>G p.L33= | Silent (SNP) | VAF 37/317 reads (12%) | called by muse, mutect2, varscan2
- REELD1 | c.546G>A p.L182= | Silent (SNP) | VAF 37/351 reads (11%) | called by muse, mutect2, varscan2
- WDR87 | c.4011C>T p.I1337= | Silent (SNP) | VAF 54/255 reads (21%) | called by muse, mutect2, varscan2
- ZFP30 | c.426C>A p.L142= | Silent (SNP) | VAF 36/202 reads (18%) | called by muse, varscan2
- PHF21A | c.1286-91T>G | Intron (SNP) | VAF 91/277 reads (33%) | called by muse, mutect2, varscan2
